Somatic mutation profile of tumor specimen TCGA-OR-A5JW-01A (aliquot TCGA-OR-A5JW-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JW, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 47.9 years (17,513 days).
Specimen TCGA-OR-A5JW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dc0b51b-62a3-438e-a498-c94c1a3fb1d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JW-10A (Blood Derived Normal), aliquot TCGA-OR-A5JW-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02ad0054-6966-4db0-ab09-6c317d097e6c

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX5 | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 114/267 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV100980148; called by muse, mutect2, varscan2
- CRACD | c.1918C>T p.R640* | Nonsense Mutation (SNP) | VAF 39/72 reads (54%) | catalogued as rs1408300514; called by muse, mutect2
- FBRS | c.240G>C p.L80F (on ENST00000287468; = p.L600F on NM_001105079.3) | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1302696219, COSV54915290; called by muse, mutect2, varscan2
- LRRC43 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs372715448; called by muse, mutect2, varscan2
- MEGF8 | c.2798G>A p.R933Q (on ENST00000251268 / NM_001271938.2; = p.R866Q on NM_001410.3) | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs1207577441; called by muse, mutect2, varscan2
- OR5H2 | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 110/148 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV62351327; called by muse, mutect2, varscan2
- OR6C2 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.041); catalogued as COSV59516385; called by muse, mutect2, varscan2
- TKTL2 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs757828647, COSV54917988; called by muse, varscan2
- ABCC6 | c.3470G>T p.S1157I | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- AKAP9 | c.3817C>A p.L1273I | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- BRINP1 | c.1873C>A p.L625I | Missense Mutation (SNP) | VAF 265/313 reads (85%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHRNA3 | c.690C>A p.D230E | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COG3 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DGKH | c.1620_1638+5del p.X540_splice | Splice Site (DEL) | VAF 36/64 reads (56%) | called by mutect2, pindel, varscan2
- DNAH3 | c.4347+2T>A p.X1449_splice | Splice Site (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- GRIN2B | c.3548C>T p.T1183M | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- KIF3A | c.194C>A p.T65N | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.079); called by muse, varscan2
- NF1 | c.5582dup p.N1861Kfs*6 (on ENST00000358273 / NM_001042492.3; = p.N1840Kfs*6 on NM_000267.3) | Frame Shift Ins (INS) | VAF 35/47 reads (74%) | called by mutect2, varscan2
- NPC1L1 | c.2966G>C p.C989S | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- OR7E24 | c.345C>A p.C115* | Nonsense Mutation (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- PCGF5 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRPS1L1 | c.499A>T p.I167F | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- SLC5A5 | c.127A>G p.S43G | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TAOK3 | c.1388G>A p.G463D | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACVR2B | c.330C>T p.N110= | Silent (SNP) | VAF 161/195 reads (83%) | catalogued as rs528729033, COSV100754159; called by muse, mutect2, varscan2
- C16orf89 | c.69G>A p.L23= | Silent (SNP) | VAF 92/229 reads (40%) | called by muse, mutect2, varscan2
- MMP8 | c.45G>T p.V15= | Silent (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- NUTM1 | c.2286G>T p.L762= | Silent (SNP) | VAF 61/136 reads (45%) | called by muse, mutect2, varscan2
- PCDH11X | c.1212C>A p.I404= | Silent (SNP) | VAF 155/182 reads (85%) | catalogued as COSV100008322, COSV100009015; called by mutect2, varscan2
- PLPPR3 | c.510C>T p.Y170= | Silent (SNP) | VAF 89/220 reads (40%) | catalogued as rs756858510; called by muse, mutect2, varscan2
